Gene-level copy-number profile of specimen HCM-WCMC-0673-C56-85A from HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ae2822d2-dc93-42b2-b990-94cb948bafee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0673-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/7c3ed9a1-51a3-4a3f-a991-fb65978c86b9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,333; copy number 2: 52,020; copy number 3: 6; copy number 4: 23.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,333. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
